Gene-level copy-number profile of tumor specimen TCGA-49-4510-01A from TCGA case TCGA-49-4510, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 51.4 years (18,762 days).
Specimen TCGA-49-4510-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.464301d7-c581-4af0-8072-f27845d94362.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-4510-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/83217cdc-a616-4152-8dcb-475cb5078f5d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 13,966; copy number 3: 15,794; copy number 4: 23,963; copy number 5: 3,357; copy number 6: 2,370; copy number 7: 276; copy number 32: 81; copy number 49: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-4510-01A-01D-1204-01): tumor purity 0.64, ploidy 3.38, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 83 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,950,754–70,637,440, 83 genes, copy number 32–49 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
